Somatic mutation profile of tumor specimen TCGA-DI-A1C3-01A (aliquot TCGA-DI-A1C3-01A-41D-A135-09) from TCGA case TCGA-DI-A1C3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 38.0 years (13,885 days).
Specimen TCGA-DI-A1C3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34a2c6b3-8591-45b8-a850-ba93a1772bec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A1C3-10A (Blood Derived Normal), aliquot TCGA-DI-A1C3-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b5175d9-e08d-4750-a52f-9474dcf45f60

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 38/118 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALKBH2 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as rs141848154; called by muse, mutect2, varscan2
- ARID5A | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100673518; called by muse, mutect2, varscan2
- COL4A6 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57873812; called by muse, mutect2
- CUX1 | c.1301C>T p.T434I (on ENST00000437600 / NM_181500.4; = p.T436I on NM_001913.5) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99474273; called by muse, mutect2, varscan2
- DDX3X | c.1039G>A p.E347K (on ENST00000399959; = p.E348K on NM_001356.5) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864051; called by muse, mutect2, varscan2
- EPN2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59060045; called by muse, mutect2, varscan2
- GABRA4 | c.408T>A p.N136K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99973442; called by muse, mutect2, varscan2
- GRM1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV51334305; called by muse, mutect2, varscan2
- H2AC15 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57586008; called by muse, mutect2, varscan2
- HCFC1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.304); catalogued as COSV60073046; called by mutect2, varscan2
- HTR2C | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52202087; called by muse, mutect2, varscan2
- KAT6B | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as rs754128910, COSV99767271; called by muse, mutect2
- LPA | c.3033C>A p.Y1011* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as COSV100305986, COSV60301325; called by muse, mutect2
- LRIG1 | c.548T>C p.F183S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99833202; called by muse, mutect2
- MAP3K15 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100133955; called by muse, mutect2
- OCA2 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV100666905; called by muse, mutect2
- P2RY14 | c.176A>T p.Y59F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99851378; called by muse, mutect2
- PGBD5 | c.1166A>G p.Y389C (on ENST00000525115; = p.Y458C on NM_001258311.2) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100358340, COSV58412554; called by muse, mutect2, varscan2
- PHLPP2 | c.2382G>T p.Q794H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100673469; called by muse, mutect2, varscan2
- PLEKHA6 | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs369254044, COSV55340267; called by muse, mutect2
- PLXNB3 | c.4609C>T p.R1537C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs369982782, COSV100737068; called by muse, mutect2, varscan2
- PRRC2B | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100621375; called by muse, mutect2, varscan2
- PTEN | c.638del p.P213Lfs*8 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as COSV64294886; called by mutect2, pindel, varscan2
- RBM12 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs1156780822, COSV58295388; called by muse, mutect2, varscan2
- RBM46 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV99907844; called by muse, mutect2
- SARDH | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as COSV100898291; called by muse, mutect2
- SNF8 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99287701; called by muse, mutect2, varscan2
- SPTA1 | c.3192C>G p.Y1064* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100934111, COSV100934153; called by muse, mutect2, varscan2
- TNS3 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs769185867, COSV100234617; called by muse, mutect2, varscan2
- TRPV6 | c.1219C>G p.L407V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs1316952386, COSV100844101, COSV100844533; called by muse, mutect2, varscan2
- KMT2D | c.13355del p.A4452Efs*67 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- LRRTM3 | c.281del p.H94Lfs*21 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- ARHGEF7 | c.900A>G p.P300= (on ENST00000375741 / NM_001113511.2; = p.P122= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs1221430971, COSV99520870; called by muse, mutect2, varscan2
- CHM | c.1356C>A p.I452= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV100752984; called by muse, mutect2, varscan2
- CNTNAP5 | c.1482C>T p.P494= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs749556691, COSV70490746; called by muse, mutect2, varscan2
- CPNE5 | c.27G>A p.S9= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV99782378; called by muse, mutect2, varscan2
- FLCN | c.135G>A p.A45= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs759930161, COSV99550051; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GUCY2C | c.1980A>G p.K660= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV99663190; called by muse, mutect2, varscan2
- ITGA7 | c.840C>T p.P280= (on ENST00000555728; = p.P236= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs555521550, COSV57696360, COSV99144262; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGAV | c.423G>A p.L141= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99654189; called by muse, mutect2, varscan2
- MAS1L | c.315G>A p.T105= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs757353541, COSV101009636; called by muse, mutect2, varscan2
- PPEF2 | c.312C>T p.D104= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99714074; called by muse, mutect2
